Somatic mutation profile of tumor specimen TCGA-FD-A6TA-01A (aliquot TCGA-FD-A6TA-01A-12D-A339-08) from TCGA case TCGA-FD-A6TA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 58.0 years (21,196 days).
Specimen TCGA-FD-A6TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b01a5366-1e6a-43ed-83e0-ecee8164e830.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TA-10A (Blood Derived Normal), aliquot TCGA-FD-A6TA-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d6460e-be34-46c6-a85a-fba811b24c9b

The open-access MAF lists 285 somatic variants for this specimen: 222 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 55, Nonsense Mutation 22, Splice Site 3, Splice Region 3, 5'UTR 3, Frame Shift Ins 2, Intron 2, 3'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.208-1G>A p.X70_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as rs267607717, CS085161, COSV51615983; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5620C>T p.Q1874* | Nonsense Mutation (SNP) | VAF 60/224 reads (27%) | catalogued as COSV99565861; called by muse, mutect2, varscan2
- ACOX3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as rs1391240119, COSV100711969, COSV62711408; called by muse, mutect2, varscan2
- ACTR1A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1360371362, COSV64023074; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- AKAP6 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55208959; called by muse, mutect2, varscan2
- ANP32A | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV51189424; called by muse, mutect2, varscan2
- APLP1 | c.1839C>G p.I613M (on ENST00000221891 / NM_001024807.3; = p.I612M on NM_005166.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55702300, COSV55702436; called by muse, mutect2, varscan2
- ARHGEF37 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs368884058; called by muse, mutect2, varscan2
- ARHGEF5 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs773707950, COSV50208656; called by mutect2, varscan2
- ARID1B | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV51651820, COSV51656126; called by muse, mutect2, varscan2
- ARID2 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57594854, COSV57612394; called by muse, mutect2, varscan2
- ATG14 | c.285-1G>C p.X95_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55955927, COSV99903056; called by muse, mutect2, varscan2
- ATP13A3 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV55462743; called by muse, mutect2, varscan2
- ATP1A2 | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs754878991, COSV63403028, COSV63404400; called by muse, mutect2, varscan2
- ATP5MD | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs144686863; called by muse, mutect2, varscan2
- ATP6V0A1 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.946); catalogued as COSV52871687; called by muse, mutect2, varscan2
- BCO2 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.585); catalogued as rs775447491, COSV63062897; called by muse, mutect2, varscan2
- BMP5 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.271); catalogued as COSV63702003; called by muse, mutect2, varscan2
- BTG1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as rs773792312, COSV55458422; called by muse, mutect2, varscan2
- CACNA1S | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs199758244, COSV100754582, COSV62945723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1G | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV50520817; called by muse, mutect2, varscan2
- CASC3 | c.1948C>G p.L650V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as COSV52866843; called by muse, mutect2
- CASR | c.2456G>A p.R819H (on ENST00000490131; = p.R896H on NM_000388.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs773552397, CM068561, COSV56135769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERD | c.2127C>G p.I709M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58464764; called by muse, mutect2, varscan2
- CCDC180 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.413); catalogued as COSV63828599; called by muse, mutect2, varscan2
- CCDC186 | c.1558T>A p.S520T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.12); catalogued as COSV65160882; called by muse, mutect2, varscan2
- CCDC50 | c.1421C>G p.S474C (on ENST00000392455 / NM_178335.3; = p.S298C on NM_174908.4) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146128834; called by muse, mutect2, varscan2
- CCDC88B | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV57265426; called by muse, varscan2
- CCDC88B | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV57265430; called by muse, varscan2
- CCNG2 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV60353315, COSV99062287; called by muse, mutect2, varscan2
- CCT8 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs776680408, COSV54503461, COSV54505354; called by muse, mutect2, varscan2
- CDON | c.3721G>A p.E1241K (on ENST00000392693 / NM_001243597.2; = p.E1218K on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54996284, COSV99701836; called by muse, mutect2, varscan2
- CDRT1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55411182; called by muse, mutect2, varscan2
- CENPH | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51584529; called by muse, mutect2, varscan2
- CEP85L | c.2234C>A p.S745* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100874213; called by muse, mutect2, varscan2
- CFAP46 | c.7613G>A p.R2538K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54150587; called by muse, mutect2, varscan2
- CHGB | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66759971; called by muse, mutect2, varscan2
- CLOCK | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100011820, COSV59402690; called by muse, mutect2, varscan2
- CLVS2 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV51560293; called by muse, mutect2, varscan2
- COL19A1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV59568972; called by muse, mutect2, varscan2
- COL7A1 | c.6573G>A p.P2191= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as rs779416907, COSV60393320; called by muse, varscan2
- CORO2B | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55951533; called by muse, mutect2, varscan2
- CTSF | c.1113G>C p.E371D | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV59748041; called by muse, mutect2, varscan2
- CUBN | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV64701360; called by muse, mutect2, varscan2
- DDOST | c.954G>C p.E318D (on ENST00000415136; = p.E301D on NM_005216.5) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs144834631; called by mutect2, varscan2
- DDX42 | c.2469G>C p.E823D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV63789720; called by muse, mutect2, varscan2
- DEFB129 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55730913; called by muse, mutect2, varscan2
- DENND2C | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV67920678, COSV67922536; called by muse, mutect2, varscan2
- DHX30 | c.2948C>G p.S983* (on ENST00000445061 / NM_138615.3; = p.S944* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as rs1290128833, COSV99275458; called by muse, mutect2, varscan2
- DHX37 | c.1575G>C p.K525N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58133066; called by muse, mutect2, varscan2
- DNAH11 | c.5335C>G p.Q1779E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100179377, COSV60972086; called by muse, mutect2
- DPYS | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV60907597; called by muse, mutect2, varscan2
- EDC4 | c.3118G>C p.E1040Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV59302291; called by muse, mutect2, varscan2
- EIF3A | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV64960841; called by muse, mutect2, varscan2
- EML5 | c.3356G>T p.G1119V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61343457; called by muse, mutect2, varscan2
- EVPL | c.4186G>C p.D1396H | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56908952; called by muse, mutect2, varscan2
- EXO1 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs753952700, COSV62216958; called by muse, mutect2, varscan2
- EYA1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV104411316, COSV58159549; called by muse, mutect2, varscan2
- EYA4 | c.1026C>G p.I342M (on ENST00000531901 / NM_001301013.1; = p.I336M on NM_004100.5) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as COSV62048657; called by muse, mutect2, varscan2
- F8 | c.5209C>G p.L1737V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as COSV100811688, COSV64271136, COSV64276619; called by muse, mutect2, varscan2
- FAM217A | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs374965334, COSV51159375; called by muse, mutect2, varscan2
- FAM83H | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948210399, COSV66353643, COSV66354317; called by muse, mutect2, varscan2
- FAN1 | c.1941G>A p.L647= | Splice Region (SNP) | VAF 29/91 reads (32%) | catalogued as COSV62950140; called by muse, mutect2, varscan2
- FANCD2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs1231761206, COSV55033207; called by muse, varscan2
- FASTKD5 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV53905064; called by muse, mutect2, varscan2
- FBXO47 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65241477; called by muse, mutect2
- FER1L5 | c.5886G>C p.Q1962H (on ENST00000623019; = p.Q1926H on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV53841009; called by muse, mutect2, varscan2
- FGF11 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs765090559, COSV53439234; called by muse, mutect2, varscan2
- FLI1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV55643455; called by muse, mutect2, varscan2
- FLNC | c.5656G>A p.D1886N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV100367779, COSV57953054; called by muse, mutect2, varscan2
- FNIP2 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.079); catalogued as COSV52438258; called by muse, mutect2, varscan2
- GAS8 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1251019358, COSV51942817; called by muse, mutect2, varscan2
- GATB | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56129564; called by muse, mutect2, varscan2
- GDE1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.077); catalogued as COSV62059262; called by muse, mutect2, varscan2
- GOLGB1 | c.5156C>T p.S1719F | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.73); catalogued as COSV61463513; called by muse, mutect2, varscan2
- GPAT3 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV52356150; called by muse, mutect2, varscan2
- GRIP1 | c.2099C>G p.S700* (on ENST00000359742 / NM_001379345.1; = p.S648* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | catalogued as COSV54043755; called by muse, mutect2, varscan2
- GTF2E1 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1283384499, COSV52203740; called by muse, mutect2, varscan2
- GYS2 | c.2038A>C p.N680H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53921605; called by muse, mutect2, varscan2
- H3C2 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52518150; called by muse, mutect2, varscan2
- HAUS3 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV54722239, COSV54724090; called by muse, mutect2, varscan2
- HSPA1B | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100989283; called by muse, mutect2, varscan2
- HSPG2 | c.11222C>G p.S3741* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV101013470; called by muse, mutect2, varscan2
- HSPG2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101012947; called by muse, mutect2, varscan2
- HSPH1 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV60710797; called by muse, mutect2, varscan2
- HUS1B | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV57862997; called by muse, mutect2, varscan2
- IL5RA | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV56522114; called by muse, mutect2, varscan2
- INTS5 | c.2872C>G p.Q958E | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as COSV57950823; called by muse, mutect2, varscan2
- ITGB1 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56480263; called by muse, mutect2, varscan2
- JAK2 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV67599195; called by muse, mutect2, varscan2
- KATNB1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781957453, COSV65559882; called by muse, mutect2, varscan2
- KCTD10 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV57326342; called by muse, mutect2, varscan2
- KDM6A | c.3556T>A p.L1186M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV100938233; called by muse, mutect2, varscan2
- KIF1B | c.2122G>T p.E708* (on ENST00000377086 / NM_001365952.1; = p.E662* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99823400; called by muse, mutect2, varscan2
- KIZ | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99852098; called by muse, mutect2
- KLHL23 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV55866381; called by muse, mutect2, varscan2
- KRTAP24-1 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100447427; called by muse, mutect2, varscan2
- LATS2 | c.2615C>G p.S872* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV66880874; called by muse, mutect2
- LPP | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV57084101; called by muse, mutect2, varscan2
- LRCH2 | c.2146C>A p.L716I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100406905, COSV100407753; called by mutect2, varscan2
- LRP1B | c.6829C>G p.H2277D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV67189320, COSV67200430; called by muse, mutect2, varscan2
- LRRC36 | c.1490G>C p.S497T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV52078786; called by muse, mutect2, varscan2
- MAP1B | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57096360; called by mutect2, varscan2
- MAP2K5 | c.1129G>A p.D377N (on ENST00000178640 / NM_145160.3; = p.D367N on NM_002757.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV51612202; called by muse, mutect2, varscan2
- MAP3K11 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763030681, COSV58418914; called by muse, mutect2, varscan2
- MARS2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.087); catalogued as COSV56570961; called by muse, mutect2, varscan2
- MB21D2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV66662492; called by muse, mutect2, varscan2
- MBD6 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV63073719; called by muse, mutect2, varscan2
- MBD6 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV63073728; called by muse, mutect2, varscan2
- MBD6 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100851684; called by muse, mutect2, varscan2
- MDN1 | c.14230G>A p.E4744K | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV65518601, COSV65519376, COSV65531504; called by muse, mutect2, varscan2
- MDN1 | c.14122G>C p.E4708Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as COSV65519384; called by muse, mutect2, varscan2
- MED13 | c.2566G>C p.E856Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV67262702; called by muse, mutect2, varscan2
- MIA3 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV60511443; called by muse, mutect2
- MKI67 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100896593; called by muse, mutect2, varscan2
- MMP10 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54245888; called by muse, mutect2, varscan2
- MPEG1 | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.319); catalogued as COSV57089386; called by muse, varscan2
- MPP6 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV56036769; called by muse, mutect2, varscan2
- MTIF3 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101137495; called by muse, mutect2
- MTOR | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63868342, COSV63869544; called by muse, mutect2, varscan2
- MYC | c.416C>G p.S139W (on ENST00000377970; = p.S154W on NM_002467.6) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52367432, COSV52370269, COSV52372085; called by muse, mutect2, varscan2
- MYH9 | c.3595G>T p.E1199* | Nonsense Mutation (SNP) | VAF 48/173 reads (28%) | catalogued as COSV99338933; called by muse, mutect2, varscan2
- NBEAL1 | c.7704G>C p.K2568N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101355517; called by muse, mutect2
- NCOA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99946165; called by muse, mutect2, varscan2
- NDE1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as rs891862718, COSV61271328; called by muse, mutect2, varscan2
- NDUFV1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.103); catalogued as COSV59595030; called by muse, mutect2, varscan2
- NKAPL | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59197329; called by muse, mutect2, varscan2
- NKX2-1 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV61387850; called by muse, mutect2, varscan2
- NME1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV50147148; called by muse, mutect2, varscan2
- NOB1 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52061158; called by muse, mutect2, varscan2
- NOD1 | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56111543; called by muse, mutect2, varscan2
- NOTCH4 | c.3296G>A p.G1099E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV66679653; called by muse, mutect2, varscan2
- NOTCH4 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV66679513, COSV66679657; called by muse, mutect2, varscan2
- NPR3 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV54085823; called by muse, mutect2, varscan2
- NQO2 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV57642600; called by muse, mutect2, varscan2
- NUDT7 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV51744904; called by muse, mutect2, varscan2
- ODF2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV63545701; called by muse, mutect2, varscan2
- PACC1 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54786912; called by muse, mutect2, varscan2
- PCDH18 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.24); catalogued as COSV61266393; called by muse, mutect2, varscan2
- PCDHAC1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV53843000, COSV53874042; called by muse, mutect2, varscan2
- PLCB4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.079); catalogued as rs1031175453, COSV53797106; called by muse, mutect2, varscan2
- PLCL2 | c.1658C>T p.S553F (on ENST00000615277 / NM_001144382.2; = p.S427F on NM_015184.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV67621334; called by muse, mutect2, varscan2
- PLXNA2 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV65439119; called by muse, mutect2, varscan2
- POLG | c.2288G>A p.G763E | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51520430; called by muse, mutect2, varscan2
- PPAT | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV51703258, COSV99947291; called by muse, mutect2, varscan2
- PPP1R8 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52579337; called by muse, mutect2, varscan2
- PREPL | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs1198009036, COSV99576205; called by muse, mutect2, varscan2
- PRSS3 | c.356G>C p.G119A (on ENST00000361005 / NM_007343.4; = p.G227A on NM_002771.3) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61554440; called by muse, mutect2, varscan2
- PTPRB | c.5782G>A p.D1928N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54237024; called by muse, mutect2, varscan2
- PTPRC | c.3917C>T p.S1306L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as COSV61408693; called by muse, mutect2, varscan2
- RANBP1 | c.240C>G p.H80Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59334462; called by muse, mutect2, varscan2
- RASAL3 | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54606202; called by muse, mutect2, varscan2
- RBM10 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as COSV61309517; called by muse, mutect2, varscan2
- RFTN2 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV54387161; called by muse, mutect2, varscan2
- RHD | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.188); catalogued as COSV59645696; called by muse, varscan2
- RIMS1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1388046078, COSV53436956, COSV53444904, COSV53447148; called by muse, mutect2, varscan2
- RPL23 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55559667; called by muse, mutect2, varscan2
- RPS18 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV101005639; called by muse, mutect2, varscan2
- SAA2 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99879339; called by muse, mutect2, varscan2
- SAMM50 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV63109547; called by muse, mutect2, varscan2
- SELENOO | c.1502+1G>T p.X501_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99955625; called by muse, mutect2
- SENP5 | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs780088866, COSV60206636; called by muse, mutect2, varscan2
- SERPINA6 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58584126; called by muse, mutect2, varscan2
- SLC25A41 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773600877, COSV58599416; called by muse, mutect2, varscan2
- SLC35B3 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59468114; called by muse, mutect2, varscan2
- SLC4A7 | c.3598G>C p.E1200Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV55395879; called by muse, mutect2, varscan2
- SLCO5A1 | c.2378G>C p.R793T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs937581729, COSV52656324, COSV99479145; called by muse, mutect2, varscan2
- SMARCA4 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1060502073, COSV60790239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCAD1 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62773553; called by muse, mutect2, varscan2
- SNX19 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56284722; called by muse, mutect2, varscan2
- SNX19 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs757952791, COSV56284731; called by muse, mutect2, varscan2
- SOS1 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV67674481; called by muse, mutect2, varscan2
- SPTBN2 | c.6631C>G p.R2211G | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1333503788, COSV59449429; called by muse, mutect2, varscan2
- ST3GAL6 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99504930, COSV99505119; called by muse, mutect2, varscan2
- STAG2 | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV54369300, COSV99493621; called by muse, mutect2, varscan2
- STAU2 | c.120C>A p.F40L (on ENST00000524300 / NM_001164380.2; = p.F8L on NM_014393.2) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV62474758; called by muse, mutect2, varscan2
- STK4 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100860184; called by muse, mutect2, varscan2
- STOM | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as COSV54417817; called by muse, mutect2, varscan2
- SUPT16H | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV53523279, COSV99359513; called by muse, mutect2, varscan2
- SV2C | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1201547566, COSV59217261; called by muse, mutect2, varscan2
- SVIL | c.6243G>T p.K2081N (on ENST00000355867 / NM_021738.3; = p.K1655N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63441658; called by muse, varscan2
- SYNJ2 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as rs751616283, COSV62896315; called by muse, mutect2, varscan2
- TANC2 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV67332350; called by muse, mutect2, varscan2
- TAS2R4 | c.549G>C p.L183F | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV56093366, COSV56093550; called by muse, mutect2, varscan2
- TAS2R5 | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV56094636; called by muse, mutect2, varscan2
- TBCE | c.1225C>G p.Q409E (on ENST00000366601; = p.Q472E on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV64003601; called by muse, mutect2, varscan2
- TCHH | c.5158G>C p.E1720Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); catalogued as COSV64273805; called by muse, mutect2, varscan2
- TCP1 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58458025; called by muse, mutect2, varscan2
- TEAD3 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV58816170; called by muse, mutect2, varscan2
- TECPR1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs749799075, COSV101130191, COSV65782670; called by muse, mutect2, varscan2
- TECTA | c.5165G>C p.C1722S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50695977; called by muse, mutect2, varscan2
- TGFBI | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59350593; called by muse, mutect2
- TLCD1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV52043767; called by muse, mutect2, varscan2
- TMEFF2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55830095; called by muse, mutect2, varscan2
- TMOD2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV51043155; called by muse, mutect2, varscan2
- TRIAP1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1427000129, COSV56663504; called by muse, mutect2, varscan2
- TRIOBP | c.1318G>C p.A440P | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV60375408; called by muse, varscan2
- TRRAP | c.9064C>A p.Q3022K (on ENST00000359863 / NM_001244580.1; = p.Q2993K on NM_003496.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV62841714; called by muse, mutect2, varscan2
- UACA | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV59854447; called by muse, mutect2, varscan2
- UBE2L3 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100641541; called by muse, mutect2, varscan2
- UBTF | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV57185424; called by muse, mutect2, varscan2
- UNC13B | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.932); catalogued as COSV65933016; called by muse, mutect2, varscan2
- USH2A | c.9809G>A p.R3270K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56337746; called by muse, mutect2
- WASHC4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59889013; called by muse, varscan2
- ZBTB2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV57312083; called by muse, mutect2, varscan2
- ZBTB45 | c.1278G>A p.S426= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as rs193145146; called by muse, mutect2, varscan2
- ZC3HAV1 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54294442; called by muse, mutect2
- ZFP69B | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64315099; called by muse, mutect2, varscan2
- ZFP69B | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774650239, COSV64315216; called by muse, varscan2
- ZFP69B | c.1435C>G p.H479D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64315223; called by muse, varscan2
- ZNF285 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58408412; called by muse, mutect2, varscan2
- ZNF337 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.522); catalogued as rs370233494; called by muse, mutect2, varscan2
- ZNF365 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.744); catalogued as rs779285297, COSV101237963, COSV67925670; called by muse, mutect2
- ZNF440 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as rs780215713, COSV58370732; called by muse, mutect2, varscan2
- ZNF451 | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV62597140; called by muse, mutect2, varscan2
- ZNF574 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55902450; called by muse, mutect2, varscan2
- ZNF700 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.577); catalogued as COSV54311526; called by muse, mutect2, varscan2
- ZSWIM8 | c.5028G>C p.E1676D (on ENST00000605216 / NM_001242487.2; = p.E1681D on NM_015037.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.826); catalogued as COSV55213498; called by muse, mutect2, varscan2
- CCT8 | c.110_111dup p.E38Rfs*16 | Frame Shift Ins (INS) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- FOXQ1 | c.363dup p.Y122Lfs*327 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.576G>A p.A192= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV52369054; called by muse, mutect2, varscan2
- AP3D1 | c.453C>T p.I151= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs1490461219, COSV61425997; called by muse, mutect2, varscan2
- ARFGEF1 | c.3153C>T p.I1051= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV51605327; called by muse, mutect2, varscan2
- B2M | c.30C>G p.L10= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV62563463; called by muse, mutect2, varscan2
- BBS2 | c.2082G>A p.V694= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV55325672; called by muse, mutect2, varscan2
- BMP10 | c.423C>T p.I141= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV54894641; called by muse, mutect2, varscan2
- CASC3 | c.1620C>T p.I540= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV52866462; called by muse, mutect2
- CDK5RAP1 | c.858G>A p.V286= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1277739707, COSV59426360; called by muse, mutect2, varscan2
- CEACAM18 | c.661C>T p.L221= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs757459120, COSV67282523; called by muse, varscan2
- CEP55 | c.1299C>G p.L433= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV65184805; called by muse, mutect2, varscan2
- CHAD | c.945G>A p.L315= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs546573442, COSV51971827; called by muse, mutect2, varscan2
- CSNK1G3 | c.717C>T p.F239= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV62053989; called by muse, mutect2, varscan2
- DCAF15 | c.222C>G p.L74= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54335543, COSV54335978; called by muse, mutect2, varscan2
- EP400 | c.8154C>G p.L2718= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100200976, COSV57767971; called by muse, mutect2, varscan2
- ERCC4 | c.2662C>T p.L888= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs1175692417, COSV61311281; called by muse, mutect2, varscan2
- EXOC2 | c.627C>G p.L209= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV57861530, COSV57862987; called by muse, mutect2, varscan2
- FBXO40 | c.2079G>A p.E693= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV57523045; called by muse, mutect2, varscan2
- GABRD | c.1257C>G p.L419= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV66079928; called by muse, mutect2, varscan2
- GUCY1A1 | c.828G>A p.V276= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV56650426; called by muse, mutect2, varscan2
- IFNK | c.285C>T p.F95= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV51778113; called by muse, mutect2
- IL12RB1 | c.1710G>A p.L570= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV74045452; called by muse, mutect2, varscan2
- IQSEC1 | c.2706G>A p.L902= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs532278369, COSV56222560; called by muse, mutect2, varscan2
- KDM2A | c.438C>G p.L146= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67081338, COSV67081531; called by muse, mutect2, varscan2
- KRT19 | c.462G>A p.Q154= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV54178755; called by muse, mutect2, varscan2
- LDHAL6B | c.780G>A p.L260= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55684259; called by muse, mutect2, varscan2
- MBD6 | c.222C>T p.F74= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs755103228, COSV60765177; called by muse, mutect2, varscan2
- MPEG1 | c.1704C>T p.I568= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV57089377; called by muse, varscan2
- NDST3 | c.828G>A p.L276= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV56615631; called by muse, mutect2, varscan2
- OBSCN | c.1278C>G p.L426= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV52749969, COSV52756534; called by muse, mutect2, varscan2
- OR52D1 | c.144C>A p.L48= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV59487206; called by muse, mutect2, varscan2
- PHLDA3 | c.309C>T p.V103= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs773631516, COSV66210736, COSV66210818; called by muse, mutect2, varscan2
- PLCE1 | c.2967G>A p.V989= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV53343255; called by muse, mutect2, varscan2
- POMZP3 | c.174G>A p.R58= | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as COSV99300539; called by muse, mutect2, varscan2
- PRKAR1A | c.1098C>G p.L366= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV56836150; called by muse, mutect2, varscan2
- PRKDC | c.8457G>A p.E2819= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58047684; called by muse, mutect2, varscan2
- RANBP17 | c.792C>T p.F264= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV66648026; called by muse, mutect2, varscan2
- RCBTB2 | c.1050C>T p.F350= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100749609, COSV60649562; called by muse, mutect2, varscan2
- RHD | c.60G>A p.L20= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV59645689; called by muse, varscan2
- SEMA3A | c.1056C>T p.F352= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV54865368, COSV54873556; called by muse, mutect2, varscan2
- SH3TC1 | c.1668C>T p.L556= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99794882; called by muse, mutect2, varscan2
- SLC35D1 | c.90G>T p.G30= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1320408035, COSV52430687, COSV99337917; called by muse, mutect2, varscan2
- SLCO2A1 | c.1581G>C p.L527= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs145832999, COSV60488435; ClinVar: likely benign; called by muse, mutect2, varscan2
- STYXL2 | c.2436C>T p.C812= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54803638; called by muse, mutect2, varscan2
- TBKBP1 | c.237C>T p.I79= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1156919421, COSV64653435; called by muse, mutect2, varscan2
- TCHH | c.4269G>A p.L1423= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV64272791; called by muse, mutect2, varscan2
- TMEM132E | c.1125C>T p.V375= (on ENST00000321639; = p.V465= on NM_001304438.2) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1416562823, COSV58695701, COSV58701316; called by muse, mutect2, varscan2
- TMEM63C | c.984C>T p.F328= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV53602463; called by muse, mutect2, varscan2
- TNFRSF6B | c.765G>A p.L255= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs774111142, COSV53927767; called by muse, mutect2
- TSEN54 | c.483G>A p.L161= | Silent (SNP) | VAF 113/243 reads (47%) | catalogued as COSV58690431; called by muse, mutect2, varscan2
- UNC5C | c.2046C>G p.L682= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV71658816; called by muse, mutect2, varscan2
- UQCRFS1 | c.768C>G p.L256= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV59184534; called by muse, mutect2, varscan2
- USP20 | c.2718G>A p.K906= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100204356; called by muse, mutect2, varscan2
- ZMYND11 | c.990C>G p.V330= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV59077232, COSV59082474; called by muse, mutect2
- ZNF280A | c.96G>A p.L32= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV57479944; called by muse, mutect2, varscan2
- ZNF649 | c.1517G>A p.*506= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100031058, COSV56814045; called by muse, mutect2, varscan2
- CD70 | c.-1G>T | 5'UTR (SNP) | VAF 24/67 reads (36%) | catalogued as rs1450773602, COSV99835586; called by muse, mutect2, varscan2
- NR3C1 | c.-1G>C | 5'UTR (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99196331; called by muse, mutect2, varscan2
- POM121 | chr7:72948595 G>C | 3'Flank (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99988407; called by muse, mutect2, varscan2
- RPL31P57 | n.25G>T | RNA (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.127-9403C>G | Intron (SNP) | VAF 15/25 reads (60%) | catalogued as COSV65387318; called by muse, mutect2, varscan2
- SZT2 | c.*1G>C | 3'UTR (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100981286; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- WIPI2 | c.212-189G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99993342; called by mutect2, varscan2
